Somatic mutation profile of tumor specimen TARGET-20-PANGTF-09A (aliquot TARGET-20-PANGTF-09A-01D) from TARGET case TARGET-20-PANGTF, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.9 years (5,814 days).
Specimen TARGET-20-PANGTF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6954c067-54a4-471d-ad9b-f67b85ef42fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANGTF-14A (Bone Marrow Normal), aliquot TARGET-20-PANGTF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/296a7184-82f4-4936-a9b5-14afb116dcd0

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GEN1 | c.965G>A p.C322Y | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV58058565; called by muse, mutect2
- LCE1F | c.311G>C p.S104T | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.158); catalogued as COSV57669629, COSV57669714; called by muse, mutect2, varscan2
- SPAG9 | c.2800G>A p.V934M (on ENST00000262013 / NM_001130528.3; = p.V920M on NM_003971.6) | Missense Mutation (SNP) | VAF 112/300 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as COSV56243988; called by muse, mutect2, varscan2
- XDH | c.1985C>T p.T662I | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.88); catalogued as rs374486058; called by muse, mutect2, varscan2
- ANXA2 | c.361C>T p.L121= | Silent (SNP) | VAF 78/187 reads (42%) | catalogued as COSV60317656; called by muse, mutect2, varscan2
- NEDD4 | c.2010C>T p.S670= (on ENST00000508342 / NM_001284338.1; = p.S251= on NM_006154.4) | Silent (SNP) | VAF 23/493 reads (5%) | catalogued as rs191994974, COSV59060421; called by muse, mutect2
- PXN | c.1245G>A p.P415= (on ENST00000228307 / NM_001080855.3; = p.P381= on NM_002859.4) | Silent (SNP) | VAF 79/294 reads (27%) | catalogued as rs758460029, COSV57217528; called by muse, mutect2, varscan2
